Somatic mutation profile of tumor specimen MMRF_1733_1_BM_CD138pos (aliquot MMRF_1733_1_BM_CD138pos_T1_KBS5U_K11329) from MMRF case MMRF_1733, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.6 years (18,496 days).
Specimen MMRF_1733_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3568dc71-7571-46a6-b794-9204d9e9fa53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1733_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1733_1_PB_Whole_C2_KBS5U_K11330; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/166f5e3b-e3f6-4330-b9ec-39b3c9554f4f

The open-access MAF lists 92 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 22, Intron 13, Silent 11, Nonsense Mutation 3, 5'UTR 3, Splice Site 1, RNA 1, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L1 | c.2453+1G>A p.X818_splice | Splice Site (SNP) | VAF 36/181 reads (20%) | catalogued as rs780662585; called by muse, mutect2, varscan2
- C1QTNF4 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.84); catalogued as COSV100209437; called by muse, mutect2
- CADPS | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs771185889, COSV51892536; called by muse, mutect2, varscan2
- CARD14 | c.1307C>A p.A436D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100712592; called by muse, mutect2
- CREB3L1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.014); catalogued as rs370086040; called by muse, mutect2, varscan2
- FAT2 | c.11369C>T p.A3790V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs754868926, COSV99944334; called by muse, mutect2, varscan2
- GPR19 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170556024, COSV60123318; called by muse, mutect2, varscan2
- GRB10 | c.1273C>T p.R425C (on ENST00000398812; = p.R379C on NM_001001549.3) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1052491212; called by muse, mutect2
- IER2 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1022133313; called by muse, mutect2, varscan2
- IGHV3-30 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs553647220; called by muse, varscan2
- KLHDC7A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319456377, COSV68769034; called by muse, mutect2, varscan2
- MAML3 | c.3263C>G p.A1088G | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV72208883; called by muse, mutect2
- PCDHB5 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs782058253; called by muse, mutect2
- SLC4A4 | c.1667G>A p.W556* (on ENST00000264485 / NM_001098484.3; = p.W512* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV52620788; called by muse, mutect2, varscan2
- SLC6A14 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64146365; called by muse, mutect2, varscan2
- SVOP | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs573317924; called by muse, mutect2, varscan2
- ZNF496 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV54179416; called by muse, mutect2, varscan2
- ALKBH8 | c.1069C>G p.P357A | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.5765C>A p.P1922H (on ENST00000297405 / NM_001363185.1; = p.P1818H on NM_052900.3) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FKBP1A | c.139T>A p.F47I | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV3-1 | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, varscan2
- KLK12 | c.220dup p.E74Gfs*59 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- LXN | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEI1 | c.1808T>C p.I603T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MYBPH | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUTM2F | c.1337A>T p.K446M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR51E2 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- OR52L1 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- P2RY6 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
- PHOSPHO2 | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 56/245 reads (23%) | called by muse, mutect2, varscan2
- PMS1 | c.2734A>T p.I912F | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- RAVER2 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RBAK | c.1449A>C p.K483N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2
- RHBDF2 | c.1781A>G p.E594G | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2
- RHOB | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTN4 | c.2239T>G p.L747V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMC4 | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by mutect2, varscan2
- TLE1 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC18 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- ZNF726 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- CACNA1I | c.5532C>T p.D1844= | Silent (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- DVL1 | c.1740G>A p.R580= (on ENST00000378888 / NM_001330311.2; = p.R555= on NM_004421.3) | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.108A>C p.T36= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs374263393; called by muse, varscan2
- IRS2 | c.744C>T p.C248= | Silent (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- LPIN3 | c.2313C>T p.V771= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs1355071730; called by muse, mutect2, varscan2
- MED16 | c.762T>C p.R254= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as rs1397407646, COSV54126918; called by muse, mutect2
- MYH1 | c.3997C>T p.L1333= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV56852248; called by muse, mutect2, varscan2
- OR52J3 | c.375T>C p.Y125= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- OSBPL10 | c.1371C>T p.C457= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- WWC2 | c.3054T>C p.N1018= | Silent (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- ZNF462 | c.2865C>T p.N955= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as rs374899829; called by muse, mutect2, varscan2
- AAK1 | c.2680+49G>T | Intron (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- ABCC4 | c.*135T>C | 3'UTR (SNP) | VAF 61/118 reads (52%) | called by muse, mutect2, varscan2
- AC021218.1 | n.2274A>C | RNA (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- AEBP1 | c.*233G>A | 3'UTR (SNP) | VAF 62/88 reads (70%) | called by muse, mutect2, varscan2
- APOL1 | c.*372A>G | 3'UTR (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2
- BNIP2 | c.296-733G>A | Intron (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- CREBZF | c.*288-96C>T | Intron (SNP) | VAF 27/223 reads (12%) | called by muse, mutect2, varscan2
- DLX1 | c.513+255G>T | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- EYS | c.1766+3578T>C | Intron (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2
- FBLN2 | c.*184C>T | 3'UTR (SNP) | VAF 23/165 reads (14%) | catalogued as rs778711885; called by muse, varscan2
- FOXG1 | c.-55G>A | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- GLDN | c.*1272dup | 3'UTR (INS) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- IGLL5 | c.-26A>G | 5'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1459_2847+1500del | Intron (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- LRCH3 | c.2209-1195C>A | Intron (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- LRRC19 | c.*1636C>T | 3'UTR (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- LRRC55 | c.*35G>A | 3'UTR (SNP) | VAF 47/83 reads (57%) | catalogued as rs371603212; called by muse, mutect2, varscan2
- MED14 | c.*2456A>G | 3'UTR (SNP) | VAF 34/39 reads (87%) | called by muse, mutect2, varscan2
- MID1 | c.*2180G>A | 3'UTR (SNP) | VAF 35/38 reads (92%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851258 C>A | 5'Flank (SNP) | VAF 46/132 reads (35%) | catalogued as rs147455610; called by muse, mutect2, varscan2
- MNT | c.*102C>T | 3'UTR (SNP) | VAF 3/43 reads (7%) | catalogued as rs976590304, COSV99438415; called by muse, mutect2
- PCMTD1 | c.*2621G>T | 3'UTR (SNP) | VAF 67/315 reads (21%) | called by muse, mutect2, varscan2
- PDE10A | c.*912G>A | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- PIEZO1 | c.6324-24G>A | Intron (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- PRMT8 | c.-385G>T | 5'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- PTCH1 | c.3450-45C>T | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- RCN1 | c.*22C>A | 3'UTR (SNP) | VAF 95/181 reads (52%) | called by muse, mutect2, varscan2
- RHOT1 | c.1739+1038C>T | Intron (SNP) | VAF 115/205 reads (56%) | catalogued as rs1347006419; called by muse, mutect2, varscan2
- SLC12A1 | c.629-617T>A | Intron (SNP) | VAF 38/59 reads (64%) | catalogued as rs1205157392; called by muse, mutect2, varscan2
- SLC35B2 | c.*572A>G | 3'UTR (SNP) | VAF 56/130 reads (43%) | catalogued as rs1022502049; called by muse, mutect2, varscan2
- SLIT3 | c.*2319A>G | 3'UTR (SNP) | VAF 38/60 reads (63%) | called by muse, mutect2, varscan2
- SYCP1 | c.*282T>G | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- TAB2 | c.*1432T>G | 3'UTR (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*4786G>T | 3'UTR (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- TIPIN | c.475+1791G>C | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- TMEM132C | c.*489dup | 3'UTR (INS) | VAF 28/84 reads (33%) | catalogued as rs1043042144; called by mutect2, varscan2
- TRIQK | chr8:92885677 A>C | 3'Flank (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- TRPC4 | c.*288A>C | 3'UTR (SNP) | VAF 9/14 reads (64%) | called by mutect2, varscan2
- ZBTB34 | c.*3190C>A | 3'UTR (SNP) | VAF 11/83 reads (13%) | catalogued as COSV100044011; called by muse, mutect2, varscan2
- ZHX3 | c.*2177G>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- ZNF277 | c.293+1035G>A | Intron (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
